Somatic mutation profile of tumor specimen TCGA-EY-A1GU-01A (aliquot TCGA-EY-A1GU-01A-11D-A13L-09) from TCGA case TCGA-EY-A1GU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 66.5 years (24,304 days).
Specimen TCGA-EY-A1GU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7cc0713-a148-44eb-bebe-6e3929c0d72b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1GU-10A (Blood Derived Normal), aliquot TCGA-EY-A1GU-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4fe7b4f-763b-46f2-88aa-7aea05f2c830

The open-access MAF lists 1,485 somatic variants for this specimen: 1,087 protein-altering or splice-affecting, 363 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 870, Silent 363, Frame Shift Del 96, Nonsense Mutation 59, Frame Shift Ins 25, Splice Site 23, Intron 11, Splice Region 11, 3'UTR 10, RNA 8, In Frame Del 3, 3'Flank 3.

Variants (750 of 1,485; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309dup p.D1104Rfs*2 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- CHD4 | c.3164G>A p.R1055H (on ENST00000357008 / NM_001363606.2; = p.R1068H on NM_001273.5) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs886039915, COSV58894318; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CWC27 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.1864C>T p.R622W (on ENST00000359125 / NM_172107.4; = p.R594W on NM_004518.6) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs772405187, COSV60541032; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LYST | c.9874G>T p.E3292* | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as rs778586545, COSV101090068; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 47/92 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 38/88 reads (43%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091dup p.Y366Lfs*10 | Frame Shift Ins (INS) | VAF 7/14 reads (50%) | catalogued as rs758946412; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 17/62 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1085308042, CM090865, COSV64291362; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.491del p.K164Rfs*3 | Frame Shift Del (DEL) | VAF 47/124 reads (38%) | catalogued as rs786204900, COSV64297274; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- TTN | c.68645del p.P22882Hfs*4 (on ENST00000591111; = p.P15458Hfs*4 on NM_003319.4) | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs1559415567; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- WASF1 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as rs1562159562, COSV100846939; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.6808C>T p.Q2270* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100933149; called by mutect2, varscan2
- ABCA4 | c.6415C>T p.R2139W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61750653, CM990077, COSV64676906; ClinVar: not provided; called by muse, mutect2, varscan2
- ABCA5 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101201231; called by muse, mutect2, varscan2
- ABCC6 | c.3826C>G p.P1276A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99229350; called by muse, mutect2, varscan2
- ABHD17B | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); catalogued as rs1194192922, COSV61007053; called by muse, mutect2, varscan2
- ABL2 | c.2137G>A p.V713M (on ENST00000502732 / NM_007314.4; = p.V698M on NM_005158.5) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.428); catalogued as rs529353106, COSV100772910; called by muse, mutect2
- ABL2 | c.943G>A p.A315T (on ENST00000502732 / NM_007314.4; = p.A300T on NM_005158.5) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772911; called by muse, mutect2, varscan2
- AC005324.2 | c.458G>A p.C153Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100372024; called by muse, mutect2
- AC131160.1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100226335; called by muse, mutect2
- ACAT2 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100887178; called by muse, mutect2, varscan2
- ACP4 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567824; called by muse, mutect2, varscan2
- ACP6 | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100984238; called by muse, mutect2, varscan2
- ACR | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV99334527; called by muse, mutect2, varscan2
- ACRBP | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99976239; called by muse, mutect2, varscan2
- ACSM2B | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100313028; called by muse, mutect2, varscan2
- ACTR2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53202628; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM22 | c.2700G>A p.R900= (on ENST00000265727 / NM_001324420.2; = p.R864= on NM_016351.6 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 24/48 reads (50%) | catalogued as COSV99717855; called by muse, mutect2, varscan2
- ADAMTS8 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV99961381; called by muse, mutect2
- ADCY10 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100897013; called by muse, mutect2, varscan2
- ADCY5 | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as rs775356872, COSV100567636, COSV59201837; called by muse, mutect2, varscan2
- ADGRA1 | c.1250G>A p.G417D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV63416837; called by muse, mutect2
- ADGRB3 | c.1854G>T p.M618I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101001553; called by muse, mutect2, varscan2
- ADGRL3 | c.1687G>A p.E563K (on ENST00000506720 / NM_001322402.2; = p.E495K on NM_015236.6) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as rs759065083, COSV72229254; called by muse, mutect2, varscan2
- ADGRV1 | c.2317_2318insT p.G773Vfs*5 | Frame Shift Ins (INS) | VAF 17/55 reads (31%) | catalogued as COSV101316313; called by mutect2, pindel, varscan2
- ADRA1B | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60700446; called by muse, mutect2, varscan2
- ADRB1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV100992303; called by muse, mutect2, varscan2
- ADSS1 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.147); catalogued as COSV100272397; called by muse, mutect2, varscan2
- AFAP1L1 | c.860C>G p.T287S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV57046180, COSV99696056; called by muse, mutect2, varscan2
- AFF2 | c.3299C>T p.A1100V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV99665597; called by muse, varscan2
- AFF4 | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as COSV99535248; called by muse, mutect2, varscan2
- AGAP1 | c.1766C>T p.A589V (on ENST00000304032 / NM_001037131.3; = p.A536V on NM_014914.5) | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs558257856, COSV100366670; called by muse, mutect2, varscan2
- AGO2 | c.1396C>A p.H466N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99596198; called by muse, mutect2, varscan2
- AGXT2 | c.59G>T p.R20M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV99183752; called by muse, mutect2, varscan2
- AHCTF1 | c.987-1G>A p.X329_splice (on ENST00000366508; = p.X303_splice on NM_015446.5) | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100404192; called by muse, mutect2, varscan2
- AHNAK2 | c.11032C>T p.Q3678* | Nonsense Mutation (SNP) | VAF 58/134 reads (43%) | catalogued as COSV100318536, COSV60917490; called by muse, mutect2
- AHNAK2 | c.10670C>A p.P3557H | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100318537; called by muse, mutect2
- AIM2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100931127; called by muse, mutect2, varscan2
- AKAP13 | c.2135C>A p.P712Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100774290; called by muse, mutect2
- ALAS1 | c.1594G>A p.V532M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100050442; called by muse, mutect2, varscan2
- ALKBH4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1414519977, COSV99479497; called by muse, mutect2, varscan2
- ALPK2 | c.3791G>A p.G1264D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV100864706; called by muse, mutect2, varscan2
- ALPP | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101235176; called by mutect2, varscan2
- AMFR | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99316142; called by muse, mutect2, varscan2
- AMIGO3 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100246692; called by muse, mutect2, varscan2
- ANK1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs563833117, COSV55884212; ClinVar: uncertain significance; called by muse, varscan2
- ANKAR | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55612878; called by muse, mutect2, varscan2
- ANKRD10 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as rs757769685, COSV99941230; called by muse, varscan2
- ANKRD20A4P | c.1692G>T p.E564D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV62007967; called by mutect2, varscan2
- ANKRD34A | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100041366; called by muse, mutect2
- ANKRD55 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747705689, COSV100591538; called by muse, varscan2
- ANKRD6 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV100330249; called by muse, mutect2, varscan2
- ANKRD6 | c.1796C>A p.P599H (on ENST00000339746 / NM_001242809.2; = p.P594H on NM_014942.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100330251; called by muse, mutect2
- ANKS6 | c.1823C>T p.T608I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs756965889, COSV100782367; called by muse, mutect2, varscan2
- ANO9 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as rs780486405, COSV60385445; called by muse, mutect2, varscan2
- ANXA4 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99247877; called by muse, mutect2, varscan2
- AP3B2 | c.2368A>G p.S790G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as COSV99916848; called by muse, mutect2
- APBB3 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as rs776006916, COSV100021439; called by muse, mutect2, varscan2
- APC | c.2929G>T p.G977C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99969378; called by muse, mutect2, varscan2
- APP | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544705359, COSV100696142, COSV60998085; called by muse, mutect2, varscan2
- AQP1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs546809019, COSV100311011; called by muse, mutect2, varscan2
- ARAF | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV99283387; called by muse, mutect2, varscan2
- ARFIP1 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100617259; called by muse, mutect2, varscan2
- ARHGAP33 | c.2600C>A p.P867H | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV99139448; called by muse, mutect2, varscan2
- ARHGAP35 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766484655, COSV68334013; called by muse, mutect2, varscan2
- ARHGAP6 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.14); catalogued as COSV100498842; called by muse, mutect2, varscan2
- ARHGEF10 | c.2939C>T p.T980I (on ENST00000398564; = p.T955I on NM_014629.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs919471485, COSV100035253; called by muse, mutect2, varscan2
- ARHGEF37 | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as COSV100382272; called by muse, mutect2
- ARHGEF40 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.804); catalogued as COSV100070586; called by muse, mutect2, varscan2
- ARID1B | c.2650G>T p.G884* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1554226059, COSV99271071; called by muse, mutect2, varscan2
- ARID4B | c.3210G>T p.E1070D | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99936104; called by muse, mutect2, varscan2
- ARL13B | c.1120C>T p.P374S (on ENST00000394222 / NM_001174150.2; = p.P267S on NM_144996.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.074); catalogued as COSV100115717; called by muse, mutect2, varscan2
- ARMC12 | c.309G>T p.E103D (on ENST00000373866 / NM_001286574.2; = p.E130D on NM_145028.5) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99849552; called by muse, mutect2, varscan2
- ARMC12 | c.776G>A p.S259N (on ENST00000373866 / NM_001286574.2; = p.S286N on NM_145028.5) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as rs142225292; called by muse, varscan2
- ARMC5 | c.2465C>A p.P822Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs541808983, COSV99192728; called by muse, varscan2
- ARSI | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV100156073; called by muse, mutect2, varscan2
- ASF1B | c.475A>G p.R159G | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99654367; called by muse, mutect2, varscan2
- ASTN1 | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99922684; called by muse, mutect2, varscan2
- ASTN2 | c.3523C>T p.R1175* (on ENST00000313400 / NM_001365069.1; = p.R1124* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99941287; called by muse, mutect2, varscan2
- ATAD1 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1241298080, COSV100058382; called by muse, mutect2, varscan2
- ATAD2 | c.3056C>A p.P1019H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99785109; called by muse, mutect2, varscan2
- ATAD2 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs754616552, COSV54883131; called by muse, varscan2
- ATF6 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.046); catalogued as COSV100909366; called by muse, mutect2, varscan2
- ATOH8 | c.872G>C p.S291T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as COSV100092779; called by muse, mutect2, varscan2
- ATP10D | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 24/45 reads (53%) | catalogued as COSV99905999; called by muse, mutect2, varscan2
- ATP11A | c.1992-1G>T p.X664_splice | Splice Site (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52106160; called by muse, mutect2, varscan2
- ATP2A3 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99989545; called by muse, mutect2, varscan2
- ATP2C2 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99298482; called by muse, mutect2, varscan2
- ATP9A | c.2205+1G>C p.X735_splice | Splice Site (SNP) | VAF 36/109 reads (33%) | catalogued as COSV100125452; called by muse, mutect2, varscan2
- ATRNL1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1345889859, COSV100746700; called by muse, mutect2
- ATRX | c.3145del p.I1049* | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as COSV64885073; called by mutect2, pindel, varscan2
- ATXN7 | c.1918A>C p.S640R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV99895073; called by mutect2, varscan2
- AURKA | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57168048; called by muse, mutect2
- AUTS2 | c.1807C>G p.L603V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100719083, COSV61384022; called by muse, mutect2, varscan2
- AVPI1 | c.287G>T p.R96I | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV101033347; called by muse, mutect2, varscan2
- B3GNT4 | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as rs972389008, COSV99928087, COSV99928322; called by muse, varscan2
- BACE1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as rs775880264, COSV100475247; called by muse, mutect2
- BAZ2B | c.3171G>T p.K1057N | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99681037; called by muse, mutect2, varscan2
- BCL6 | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99215927; called by muse, mutect2, varscan2
- BCL9 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99325656; called by muse, mutect2, varscan2
- BCR | c.3271G>A p.V1091M | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs778229520, COSV100006110; called by muse, varscan2
- BICC1 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99570798; called by muse, mutect2, varscan2
- BMP2K | c.1617G>C p.Q539H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs761287817, COSV100621880; called by muse, mutect2, varscan2
- BMPER | c.1792T>C p.Y598H | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.257); catalogued as rs570211162, COSV99780227; called by muse, mutect2, varscan2
- BRD4 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99651203; called by muse, mutect2, varscan2
- BRIP1 | c.1941G>T p.W647C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786202760, CM053145, COSV99370727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSX | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100545301; called by muse, mutect2, varscan2
- BTBD1 | c.863-1G>T p.X288_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99915638; called by muse, mutect2
- BTBD6 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100527622; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 15/26 reads (58%) | catalogued as rs752512017; called by mutect2, varscan2
- BTLA | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV100569797; called by muse, mutect2, varscan2
- C1orf127 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100983504; called by muse, mutect2, varscan2
- C2orf16 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as rs781531966, COSV62678104; called by muse, mutect2, varscan2
- C2orf78 | c.1364del p.P455Rfs*28 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as COSV68517668; called by mutect2, varscan2
- C6orf136 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99528143; called by muse, mutect2
- C6orf47 | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100789039; called by muse, mutect2, varscan2
- C8A | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs145559867; called by muse, mutect2, varscan2
- C9orf72 | c.1044G>A p.M348I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101186539; called by muse, mutect2, varscan2
- CABP2 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV53710049, COSV99590886; called by muse, mutect2, varscan2
- CACNA1C | c.2408A>C p.K803T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as COSV100221206; called by muse, mutect2
- CACTIN | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV50276322; called by muse, mutect2, varscan2
- CACYBP | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100871554; called by muse, mutect2, varscan2
- CAMKK2 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.363); catalogued as rs142766604; called by muse, mutect2, varscan2
- CAMSAP3 | c.1477A>G p.K493E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs1190262081, COSV99351648; called by muse, mutect2, varscan2
- CAMTA1 | c.1755C>G p.D585E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1405840693, COSV100351865; called by muse, mutect2, varscan2
- CAMTA1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as COSV100351866; called by muse, varscan2
- CANX | c.290T>A p.I97N | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99910607; called by muse, mutect2, varscan2
- CAPN13 | c.793T>C p.W265R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV99700786; called by muse, mutect2, varscan2
- CARS1 | c.2087A>G p.D696G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1257182118, COSV99543304; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs770159446; called by mutect2, varscan2
- CASD1 | c.1715G>A p.G572D | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.076); catalogued as rs1562949074, COSV99802325; called by muse, mutect2, varscan2
- CASKIN2 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100050763; called by muse, mutect2
- CATSPERE | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV100835297; called by muse, mutect2, varscan2
- CBWD1 | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100071159; called by muse, mutect2, varscan2
- CC2D2A | c.2978C>T p.A993V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV101052804; called by muse, mutect2, varscan2
- CCBE1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV101232857; called by muse, mutect2, varscan2
- CCDC191 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99878611; called by muse, mutect2, varscan2
- CCDC57 | c.2491C>T p.Q831* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV101052040; called by muse, mutect2, varscan2
- CCDC61 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs781488656, COSV99625651; called by muse, mutect2
- CCDC7 | c.3923A>G p.Y1308C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100179053; called by muse, mutect2, varscan2
- CCDC80 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99245126; called by muse, mutect2, varscan2
- CCNG2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100313324; called by muse, mutect2, varscan2
- CCR7 | c.713C>G p.A238G | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV99878784; called by muse, mutect2, varscan2
- CCT7 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99241069; called by muse, mutect2, varscan2
- CD14 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV100117612; called by muse, mutect2, varscan2
- CD151 | c.588C>G p.D196E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs753891282, COSV100431870; called by muse, mutect2, varscan2
- CD300C | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as rs201817334; called by muse, mutect2, varscan2
- CD320 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370038440; called by muse, mutect2
- CD53 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV54763452, COSV99602346; called by muse, mutect2, varscan2
- CDC40 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100309520; called by muse, mutect2, varscan2
- CDC73 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as CM078337, COSV66465843, COSV66466827; called by muse, mutect2
- CDCP2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs747760888, COSV61285333; called by muse, mutect2, varscan2
- CDH16 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.867); catalogued as COSV100234080; called by muse, mutect2, varscan2
- CDH18 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs748451804, COSV56905173; called by muse, mutect2, varscan2
- CDH23 | c.2440G>C p.V814L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs1238266145, COSV99822998; called by muse, mutect2, varscan2
- CDK13 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs934764468, COSV51706512; called by muse, mutect2, varscan2
- CDK17 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99702964; called by muse, varscan2
- CDK20 | c.742A>G p.M248V (on ENST00000325303 / NM_001039803.3; = p.M227V on NM_012119.4) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs775960700, COSV100308194; called by muse, mutect2, varscan2
- CDKL1 | c.673A>T p.R225W | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99367774; called by muse, mutect2, varscan2
- CDKL5 | c.2311C>T p.L771F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV101184423; called by muse, mutect2, varscan2
- CDON | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV99701802; called by muse, mutect2, varscan2
- CEACAM19 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100715499; called by muse, mutect2, varscan2
- CEBPE | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52830212; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 13/26 reads (50%) | catalogued as rs375852685; called by mutect2, varscan2
- CELF3 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99310546; called by muse, mutect2, varscan2
- CELF5 | c.102del p.Q35Sfs*5 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as COSV53011441; called by mutect2, pindel, varscan2
- CENPV | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs747169529, COSV100233511; called by muse, mutect2, varscan2
- CEP128 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.481); catalogued as rs138204688; called by muse, mutect2, varscan2
- CEP192 | c.7375C>G p.L2459V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.426); catalogued as COSV100381836; called by muse, mutect2, varscan2
- CEP290 | c.946A>T p.I316F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100469454; called by muse, mutect2, varscan2
- CEP44 | c.965G>T p.R322I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as COSV99639692; called by muse, mutect2, varscan2
- CERS4 | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1425639931, COSV99250757; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.725G>T p.W242L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100291973; called by muse, mutect2, varscan2
- CFH | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100808718; called by muse, mutect2, varscan2
- CFLAR | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100009734; called by muse, mutect2, varscan2
- CGB1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.877); catalogued as COSV100031728; called by muse, mutect2
- CHAD | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99366292; called by muse, mutect2, varscan2
- CHL1 | c.3193A>G p.T1065A (on ENST00000397491 / NM_001253387.1; = p.T1081A on NM_006614.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs1207696188, COSV99851943; called by muse, mutect2, varscan2
- CHRM3 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 8/105 reads (8%) | catalogued as COSV55101907; called by muse, mutect2
- CHRNA10 | c.1164T>G p.C388W | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99167228; called by muse, mutect2, varscan2
- CHRNA4 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs762808071, COSV100937463; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHSY3 | c.1985A>G p.D662G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100519716; called by muse, mutect2, varscan2
- CHTF18 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.195); catalogued as COSV99135807, COSV99135936; called by mutect2, varscan2
- CIART | c.809del p.P270Lfs*15 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs1560055008; called by mutect2, pindel, varscan2
- CIITA | c.3116T>C p.L1039P | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100162465; called by muse, mutect2, varscan2
- CILP2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs746138110, COSV99365051; called by muse, mutect2, varscan2
- CIT | c.4594C>A p.H1532N | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as COSV55879344, COSV99950514; called by muse, mutect2, varscan2
- CLCN5 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs782746421, COSV100260335; called by muse, mutect2, varscan2
- CLCN5 | c.1693A>G p.N565D | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100260337; called by muse, mutect2, varscan2
- CLEC17A | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs755048797, COSV60428857, COSV60430726; called by muse, mutect2, varscan2
- CLRN2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.904); catalogued as COSV101492693; called by muse, mutect2, varscan2
- CMAS | c.261-1G>A p.X87_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99982725; called by muse, mutect2, varscan2
- CNGB1 | c.2605G>A p.V869I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs61735107; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTLN | c.4175del p.K1392Rfs*3 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs747411468; called by pindel, varscan2
- CNTN4 | c.2609G>A p.S870N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100639538; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 14/18 reads (78%) | catalogued as rs374805044; called by mutect2, varscan2
- COBLL1 | c.1888A>G p.N630D (on ENST00000392717; = p.N592D on NM_014900.5) | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99528494; called by muse, mutect2, varscan2
- COL11A2 | c.2281G>A p.V761I (on ENST00000341947 / NM_080680.3; = p.V654I on NM_080679.2) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV59497705; called by muse, mutect2, varscan2
- COL1A2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.695); catalogued as COSV99800632; called by muse, mutect2, varscan2
- COL20A1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100491135; called by muse, mutect2, varscan2
- COL21A1 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99779688; called by muse, mutect2, varscan2
- COL27A1 | c.4237G>C p.A1413P | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100621218; called by muse, mutect2, varscan2
- COL3A1 | c.1201G>A p.A401T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.207); catalogued as rs373858715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMMD1 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.187); catalogued as COSV100312869; called by muse, mutect2, varscan2
- COPA | c.1915C>G p.L639V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV99616469; called by muse, mutect2
- COQ2 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.083); catalogued as COSV100270073; called by muse, mutect2
- COX16 | c.165del p.K55Nfs*2 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs759241200; called by mutect2, varscan2
- CPD | c.2608C>T p.L870F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99853168; called by muse, mutect2, varscan2
- CR1 | c.5446A>G p.I1816V | Missense Mutation (SNP) | VAF 77/304 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.124); catalogued as rs1321472936, COSV100887947; called by muse, mutect2, varscan2
- CRACD | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.089); catalogued as rs755012372, COSV99949805; called by muse, varscan2
- CRACDL | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV101194110; called by muse, mutect2, varscan2
- CRAMP1 | c.2260A>G p.T754A | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1390287107, COSV99246294; called by muse, mutect2, varscan2
- CRB1 | c.3013G>A p.D1005N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as COSV66329684, COSV66332744; called by muse, varscan2
- CRB1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs563857130, COSV66328727, COSV66328731; called by muse, varscan2
- CRNN | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55122429; called by muse, mutect2
- CSE1L | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522166; called by muse, mutect2, varscan2
- CSMD1 | c.5809G>A p.V1937M (on ENST00000520002; = p.V1936M on NM_033225.6) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1463953308, COSV59289846; called by muse, mutect2, varscan2
- CSMD2 | c.7462G>A p.G2488R | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374084658; called by muse, mutect2, varscan2
- CTDP1 | c.2615G>T p.S872I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99310965; called by muse, mutect2, varscan2
- CTNNAL1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs747944532, COSV57702470, COSV57705583; called by muse, mutect2, varscan2
- CTSL | c.399T>C p.G133= | Splice Region (SNP) | VAF 32/116 reads (28%) | catalogued as COSV100446726; called by muse, mutect2, varscan2
- CWC15 | c.163C>A p.R55S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as COSV99688430, COSV99688606; called by muse, mutect2, varscan2
- CWF19L2 | c.977del p.N326Ifs*19 | Frame Shift Del (DEL) | VAF 43/105 reads (41%) | catalogued as COSV56519025; called by mutect2, pindel, varscan2
- CWH43 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99893820; called by muse, mutect2, varscan2
- CYB5R1 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV100924858; called by muse, mutect2
- CYB5R3 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs547268043, COSV61545655; called by muse, mutect2, varscan2
- CYP11B1 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as rs564754333, COSV99455522; called by muse, mutect2, varscan2
- CYP11B1 | c.493G>C p.A165P | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99455523; called by muse, mutect2
- CYP27C1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.727); catalogued as rs547196058, COSV58869024; called by muse, mutect2, varscan2
- CYP2B6 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100137693; called by muse, mutect2
- CYP2S1 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as COSV100027557; called by muse, mutect2, varscan2
- CYP4F11 | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV99931022; called by muse, mutect2, varscan2
- CYP4F22 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99513031; called by muse, mutect2, varscan2
- DACT1 | c.2153C>T p.A718V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100242033; called by muse, mutect2, varscan2
- DAGLA | c.3017C>T p.T1006M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs765568409, COSV99944631; called by muse, varscan2
- DCAF17 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV64544603, COSV64545828; called by muse, mutect2, varscan2
- DCAF6 | c.1723A>G p.K575E (on ENST00000312263 / NM_001349778.1; = p.K595E on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100394679; called by muse, mutect2, varscan2
- DCAF8 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs750184781, COSV100470720; called by muse, mutect2, varscan2
- DCAF8L1 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV71595247, COSV71595549; called by muse, mutect2, varscan2
- DDX19A | c.1183G>T p.G395C | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100156439; called by muse, mutect2, varscan2
- DDX21 | c.609C>T p.G203= | Splice Region (SNP) | VAF 13/23 reads (57%) | catalogued as rs1398434321, COSV100826540; called by muse, mutect2, varscan2
- DENND2B | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV100567700; called by muse, mutect2
- DENND2B | c.726G>T p.E242D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.628); catalogued as COSV100567703; called by muse, mutect2, varscan2
- DENND4B | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs188117139; called by muse, mutect2, varscan2
- DGAT1 | c.1153T>A p.C385S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV100184148; called by muse, mutect2, varscan2
- DGCR6L | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs145876189; called by mutect2, varscan2
- DGKQ | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs763724957, COSV99893035; called by muse, varscan2
- DHRS9 | c.669dup p.L224Tfs*21 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX37 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as rs761194412, COSV100439422; called by mutect2, varscan2
- DHX57 | c.3442C>G p.Q1148E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99769825; called by muse, mutect2, varscan2
- DHX57 | c.2896G>T p.G966C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99769827; called by muse, mutect2, varscan2
- DHX9 | c.3751G>T p.G1251C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.423); catalogued as COSV100841348, COSV100841485; called by muse, mutect2, varscan2
- DIPK1B | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.877); catalogued as rs368865388; called by muse, mutect2, varscan2
- DISP3 | c.3323C>T p.A1108V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs779635425, COSV99609619; called by muse, mutect2, varscan2
- DMBT1 | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs1308522345, COSV100352278, COSV100353818; called by muse, mutect2
- DMBT1 | c.7294G>A p.V2432M (on ENST00000338354 / NM_001377530.1; = p.V1675M on NM_004406.3) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs368058687; called by muse, mutect2, varscan2
- DMRT2 | c.1333C>A p.L445M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV99426196; called by muse, mutect2, varscan2
- DMXL2 | c.1804C>T p.H602Y | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99197626; called by muse, mutect2
- DNAH17 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV101103137; called by muse, mutect2, varscan2
- DNAH3 | c.8168C>T p.A2723V | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.129); catalogued as rs148454192, COSV54516556, COSV54531302; called by muse, mutect2, varscan2
- DNAH3 | c.4840G>T p.G1614* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99769621; called by muse, mutect2, varscan2
- DNAH5 | c.3110C>T p.A1037V | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV54234494, COSV99452600; called by muse, mutect2, varscan2
- DNAH7 | c.11512G>T p.G3838C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV100416738; called by muse, mutect2, varscan2
- DNAH8 | c.8219G>A p.R2740H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs763438877, COSV59427737; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH9 | c.13124C>T p.A4375V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV99307330; called by muse, mutect2, varscan2
- DNASE2 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99263485; called by muse, mutect2, varscan2
- DOCK2 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99914383; called by muse, mutect2, varscan2
- DOCK3 | c.2051C>A p.P684H | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99814143; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 29/72 reads (40%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.1648C>A p.L550M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52949899; called by muse, mutect2, varscan2
- DPH6 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99853811; called by mutect2, varscan2
- DPYSL4 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs776728939, COSV100063182; called by muse, varscan2
- DSG4 | c.1844C>A p.P615H | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as COSV100356272, COSV57395492; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs267601226; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs369293935; called by mutect2, varscan2
- EEF1A1 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100303382; called by muse, mutect2, varscan2
- EEF1A2 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); catalogued as COSV53205617; called by muse, mutect2, varscan2
- EEF1D | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as COSV99435343; called by muse, mutect2, varscan2
- EEF2 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58579495; called by muse, mutect2, varscan2
- EFCAB12 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100394763; called by muse, mutect2, varscan2
- EFL1 | c.2957C>T p.T986I | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99188057; called by muse, mutect2, varscan2
- EHMT1 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV100604109; called by muse, mutect2, varscan2
- EIF4G1 | c.2003C>A p.P668Q (on ENST00000346169 / NM_198241.3; = p.P472Q on NM_004953.5) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100072182, COSV59990453; called by muse, mutect2, varscan2
- ELAPOR1 | c.1696A>G p.T566A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.719); catalogued as rs753436038, COSV100884467; called by muse, mutect2, varscan2
- ELK4 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV99222476; called by muse, mutect2, varscan2
- ELN | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); catalogued as COSV99332980; called by muse, mutect2, varscan2
- ELOF1 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99370708; called by muse, mutect2, varscan2
- EML4 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100581163; called by muse, mutect2, varscan2
- ENOX1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV99816760; called by muse, mutect2, varscan2
- ETNK2 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV100916608; called by muse, mutect2, varscan2
- ETNK2 | c.776G>A p.S259N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV100916609; called by muse, varscan2
- EVA1C | c.635-1G>T p.X212_splice | Splice Site (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100291537; called by muse, mutect2, varscan2
- EXO1 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100800083; called by muse, mutect2, varscan2
- EXOC4 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99555073; called by muse, mutect2, varscan2
- EXOC8 | c.1601A>T p.D534V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV99150016; called by muse, varscan2
- F13B | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs868256767, COSV66372194; called by muse, mutect2, varscan2
- FAM149A | c.1598C>A p.P533H (on ENST00000356371 / NM_001367768.2; = p.P242H on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99906684; called by muse, mutect2, varscan2
- FAM151A | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100157044; called by muse, mutect2, varscan2
- FAM174A | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV100444557; called by muse, mutect2, varscan2
- FAM47B | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV100264532; called by muse, mutect2, varscan2
- FANCA | c.3197C>T p.A1066V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs1419279017, COSV99981757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCI | c.1383C>T p.D461= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100168395; called by muse, mutect2, varscan2
- FANCI | c.2381C>A p.T794N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.076); catalogued as COSV100167341, COSV100168400; called by muse, mutect2
- FARP2 | c.2544C>G p.N848K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.158); catalogued as COSV99885202; called by muse, mutect2, varscan2
- FARSB | c.339G>A p.E113= | Splice Region (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99918561; called by muse, mutect2, varscan2
- FASTKD1 | c.1066T>A p.S356T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV101328532, COSV70007227; called by muse, mutect2, varscan2
- FASTKD5 | c.722T>C p.M241T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99418426; called by mutect2, varscan2
- FAT1 | c.11738C>T p.A3913V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV71675255; called by muse, mutect2, varscan2
- FAT1 | c.1641C>G p.Y547* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV101499562; called by muse, mutect2, varscan2
- FAT2 | c.9208C>T p.L3070F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs1195237217, COSV99943822; called by muse, mutect2
- FAT3 | c.9162G>T p.K3054N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV53103481, COSV53172820; called by muse, mutect2, varscan2
- FAT3 | c.9386del p.P3129Lfs*22 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as COSV99962642; called by mutect2, pindel, varscan2
- FBXO43 | c.1212C>G p.H404Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101413902, COSV71053561; called by muse, mutect2, varscan2
- FCGBP | c.11729G>A p.W3910* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as rs1346145855; called by muse, mutect2, varscan2
- FCGBP | c.2800G>A p.V934M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1457888064; called by muse, mutect2, varscan2
- FCN3 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs748278677, COSV99585478; called by muse, varscan2
- FDCSP | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); catalogued as COSV100525826; called by muse, mutect2
- FGF1 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV100532459; called by muse, mutect2, varscan2
- FGF12 | c.529C>T p.L177F (on ENST00000454309 / NM_021032.5; = p.L115F on NM_004113.6) | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99282961; called by muse, mutect2, varscan2
- FGFR2 | c.1315A>T p.N439Y | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV100336949; called by muse, mutect2, varscan2
- FHDC1 | c.3418C>T p.P1140S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1014888285, COSV99471570; called by muse, mutect2, varscan2
- FLAD1 | c.370A>G p.K124E | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99422870; called by muse, mutect2, varscan2
- FLG | c.4922C>T p.A1641V | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100911943, COSV99056752; called by muse, mutect2, varscan2
- FLG | c.4546G>T p.G1516W | Missense Mutation (SNP) | VAF 103/436 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV100911945; called by muse, mutect2, varscan2
- FLVCR2 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV53160908; called by muse, mutect2, varscan2
- FNBP4 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV99771890; called by muse, mutect2, varscan2
- FNIP2 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.945); catalogued as COSV100033140; called by muse, mutect2
- FOXM1 | c.28A>G p.I10V | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1312257131, COSV100700888; called by muse, mutect2, varscan2
- FOXO3 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100670094; called by muse, mutect2, varscan2
- FOXP1 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100562167; called by muse, mutect2, varscan2
- FRMD3 | c.1349G>A p.S450N | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV100171017; called by muse, mutect2, varscan2
- FRMD7 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as rs143451711, COSV100049190; called by muse, mutect2, varscan2
- FSIP2 | c.17269G>C p.V5757L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as rs753314533, COSV100555931; called by muse, mutect2, varscan2
- FURIN | c.2129C>A p.P710H | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV99184759; called by muse, mutect2, varscan2
- FYB2 | c.1349C>A p.P450H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100599709; called by muse, mutect2, varscan2
- GADL1 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99244821; called by muse, mutect2, varscan2
- GALNTL5 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101217901; called by muse, mutect2, varscan2
- GANC | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100531140; called by muse, mutect2, varscan2
- GBA | c.533C>A p.P178H | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as CD972231, COSV100516430; called by muse, mutect2, varscan2
- GBP1 | c.780del p.E261Nfs*6 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | catalogued as COSV65084311; called by mutect2, pindel, varscan2
- GCC1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs376972926, COSV99133874; called by muse, mutect2, varscan2
- GCG | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757350391, COSV64961135; called by muse, mutect2
- GFRA3 | c.1024+1G>C p.X342_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99218511; called by muse, mutect2
- GGA2 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774451751, COSV100564809; called by muse, mutect2, varscan2
- GIPR | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99624856; called by muse, mutect2, varscan2
- GJC2 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100812984, COSV64513213; called by muse, mutect2, varscan2
- GLCE | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as COSV99962556; called by muse, mutect2, varscan2
- GLG1 | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99216151; called by muse, mutect2, varscan2
- GLUL | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100092193; called by muse, mutect2, varscan2
- GMPS | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1560055265, COSV55812569; called by muse, mutect2, varscan2
- GNB1L | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1218690111, COSV100284325; called by muse, mutect2, varscan2
- GOLGA1 | c.2143C>T p.H715Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99414587; called by muse, mutect2, varscan2
- GPR151 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV99695147; called by muse, mutect2, varscan2
- GPR87 | c.936A>G p.I312M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99608922; called by muse, mutect2, varscan2
- GREM2 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100547902; called by muse, mutect2, varscan2
- GRM5 | c.3349C>T p.P1117S (on ENST00000305447 / NM_001143831.2; = p.P1085S on NM_000842.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.885); catalogued as COSV100553619; called by muse, mutect2
- GRM6 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV51439777; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2I | c.566del p.L189* | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as COSV60399209; called by mutect2, pindel, varscan2
- H2BC18 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100516154; called by muse, mutect2, varscan2
- HABP2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs529346597, COSV63637721; called by muse, mutect2, varscan2
- HAUS6 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV100997886, COSV65840821; called by muse, mutect2, varscan2
- HAUS6 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV100998150; called by muse, mutect2, varscan2
- HCAR2 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV100186595; called by muse, mutect2, varscan2
- HCAR3 | c.1019G>A p.G340D | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100811710; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HCN1 | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.598); catalogued as COSV100301602, COSV57519680; called by muse, mutect2, varscan2
- HCRTR1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as rs201416198, COSV65483816; called by muse, mutect2, varscan2
- HEATR6 | c.683A>C p.D228A | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV99482525; called by muse, mutect2, varscan2
- HEMGN | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as rs1457572898, COSV52326197; called by muse, mutect2, varscan2
- HERC1 | c.10111G>A p.A3371T | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101496792; called by muse, mutect2, varscan2
- HERC2 | c.9727G>A p.V3243M | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.708); catalogued as rs771009826, COSV55327177, COSV55356273; called by muse, mutect2, varscan2
- HHIP | c.121A>G p.N41D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99667660; called by muse, mutect2, varscan2
- HIC2 | c.203G>A p.S68N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101335609; called by muse, mutect2, varscan2
- HIKESHI | c.14T>C p.L5S | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99563576; called by muse, mutect2, varscan2
- HIPK3 | c.1300dup p.C434Lfs*20 | Frame Shift Ins (INS) | VAF 26/54 reads (48%) | catalogued as rs761758734; called by mutect2, varscan2
- HIVEP1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101045543; called by muse, mutect2, varscan2
- HIVEP2 | c.7299G>T p.E2433D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV99174968; called by muse, mutect2
- HK1 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1426009362, COSV100067545; called by muse, mutect2, varscan2
- HLA-E | c.203C>G p.P68R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100931973; called by muse, mutect2, varscan2
- HLX | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as rs754490132, COSV65044324; called by muse, mutect2, varscan2
- HM13 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as COSV59438661; called by muse, mutect2, varscan2
- HMCN1 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99633710; called by muse, mutect2, varscan2
- HNF1A | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as rs1384502119, COSV99982329; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.842G>T p.G281V (on ENST00000354667 / NM_031243.3; = p.G269V on NM_002137.4) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.916); catalogued as COSV100668381; called by muse, mutect2, varscan2
- HOXA11 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs778467438, COSV99136082; called by muse, mutect2, varscan2
- HOXC6 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99679160; called by muse, mutect2, varscan2
- HOXD9 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.417); catalogued as rs1417411500, COSV99982234; called by muse, mutect2, varscan2
- HPS4 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV100404601, COSV61103052; called by muse, mutect2, varscan2
- HSP90AA1 | c.1755+2T>C p.X585_splice | Splice Site (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99355458; called by muse, mutect2, varscan2
- HSPA9 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs761237709, COSV99785276, COSV99785482; called by mutect2, varscan2
- HTR6 | c.337T>G p.S113A | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99230380; called by muse, mutect2, varscan2
- HTRA2 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | catalogued as rs771374779, COSV99239857; called by muse, mutect2, varscan2
- HUWE1 | c.5174C>T p.A1725V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99473660; called by muse, mutect2, varscan2
- IARS2 | c.2015T>A p.V672D | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100228533; called by muse, mutect2, varscan2
- IBA57 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as rs577967119, COSV100812791; called by muse, mutect2, varscan2
- ICE2 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99831734; called by muse, mutect2, varscan2
- IFNG | c.240T>A p.F80L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99971252; called by muse, mutect2, varscan2
- IFT172 | c.2831C>T p.A944V | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs759597621, COSV53137978; called by muse, mutect2, varscan2
- IGF2R | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1217705895, COSV63626277; called by muse, mutect2, varscan2
- IGHMBP2 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV99662430; called by muse, mutect2, varscan2
- IGKV1D-42 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as rs757241359; called by muse, mutect2, varscan2
- IGSF1 | c.3223C>T p.P1075S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as COSV100812237; called by muse, mutect2, varscan2
- IGSF22 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100080195; called by muse, mutect2, varscan2
- IKBKE | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV100898357; called by muse, mutect2
- IL16 | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100267942; called by muse, mutect2, varscan2
- IL1B | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs144433180, COSV54522588; called by muse, mutect2, varscan2
- IL21R | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs577126383, COSV100560400; called by muse, mutect2, varscan2
- INKA1 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100323722; called by muse, mutect2, varscan2
- INPP4A | c.2705C>T p.T902I (on ENST00000074304 / NM_001134224.1; = p.T863I on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50828531, COSV99305949; called by muse, mutect2, varscan2
- INPP4B | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as COSV99525986; called by muse, mutect2, varscan2
- INPP5A | c.1133C>A p.P378H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100704502; called by muse, mutect2, varscan2
- INTS1 | c.3769A>G p.S1257G | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV101248234; called by muse, mutect2, varscan2
- INTS4 | c.2551C>A p.L851M | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100490069; called by muse, mutect2, varscan2
- INTS5 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV100399761; called by muse, mutect2
- IPO9 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV100843525; called by muse, mutect2, varscan2
- IQCC | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV99356751; called by muse, mutect2, varscan2
- IQCE | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100383635; called by muse, mutect2, varscan2
- IQGAP3 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1233940945, COSV100752277; called by muse, mutect2, varscan2
- IRF2BP1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV56192895; called by muse, mutect2, varscan2
- IRS1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1295643078, COSV100524840; called by muse, mutect2, varscan2
- ITGA2 | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761985032, COSV99671335; called by muse, mutect2, varscan2
- ITGA4 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs202036768, COSV101223587; called by muse, mutect2, varscan2
- ITGAE | c.2101G>A p.V701M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.195); catalogued as rs781257261, COSV53995734; called by muse, mutect2, varscan2
- ITGB7 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs750166096, COSV57240432; called by muse, mutect2, varscan2
- ITIH5 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs775841123, COSV53662190; called by muse, mutect2, varscan2
- IWS1 | c.1745del p.K582Sfs*4 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs1558747232; called by mutect2, pindel, varscan2
- JAG1 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM030052, CM993741, COSV99653329; called by muse, mutect2
- JAKMIP1 | c.2143T>C p.Y715H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV101290912; called by muse, mutect2
- JARID2 | c.3682G>A p.V1228M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as rs144053937; called by muse, mutect2, varscan2
- JMJD1C | c.3284C>T p.T1095I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100550745; called by muse, mutect2, varscan2
- JPH2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs755176754, COSV100881785; called by muse, mutect2, varscan2
- KARS1 | c.1696-2A>G p.X566_splice | Splice Site (SNP) | VAF 30/80 reads (38%) | catalogued as rs1299524768, COSV100094390; called by muse, mutect2, varscan2
- KCNAB2 | c.976A>G p.N326D | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs1431748664, COSV99314551; called by muse, mutect2, varscan2
- KCNK10 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100069015; called by muse, mutect2, varscan2
- KCNQ4 | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100714394; called by muse, mutect2, varscan2
- KDM4B | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.325); catalogued as rs900640500, COSV50229176; called by muse, mutect2, varscan2
- KIAA1109 | c.10994C>G p.T3665R | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV99169718; called by muse, mutect2, varscan2
- KIAA1210 | c.5023C>A p.L1675I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.454); catalogued as COSV101274347; called by muse, mutect2, varscan2
- KIF12 | c.745C>T p.Q249* (on ENST00000640217; = p.Q111* on NM_138424.1) | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100936224; called by muse, varscan2
- KIF26A | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV100181465; called by muse, mutect2, varscan2
- KIF6 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99760145; called by muse, mutect2
- KIZ | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs781030962, COSV55686903, COSV99852289; called by mutect2, varscan2
- KLC4 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV99432372; called by muse, mutect2, varscan2
- KLHL12 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.939); catalogued as COSV100935965; called by muse, mutect2, varscan2
- KLHL13 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.902); catalogued as COSV99452261; called by muse, mutect2, varscan2
- KLHL31 | c.1082C>A p.A361D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV100911839; called by muse, mutect2, varscan2
- KMT2A | c.10555C>T p.P3519S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV100629472; called by muse, mutect2, varscan2
- KNTC1 | c.5564C>T p.S1855F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.17); catalogued as rs374343598; called by muse, mutect2, varscan2
- KPNA5 | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758816953, COSV100706369; called by muse, mutect2, varscan2
- KRT35 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.662); catalogued as rs368478762; called by muse, mutect2
- KRT40 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1412213650, COSV100898888; called by muse, mutect2, varscan2
- KRT74 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59772973; called by muse, mutect2, varscan2
- KRTAP10-12 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100554958; called by muse, mutect2, varscan2
- L3MBTL3 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.316); catalogued as COSV62386068; called by muse, mutect2, varscan2
- L3MBTL4 | c.1631C>T p.T544I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99530391; called by muse, mutect2
- LACC1 | c.332G>T p.R111M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV100354755; called by muse, mutect2, varscan2
- LAMA1 | c.6186G>A p.M2062I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV101057297; called by muse, mutect2, varscan2
- LAMA2 | c.1803G>T p.Q601H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101370726; called by muse, mutect2, varscan2
- LAMA4 | c.2342C>T p.A781V (on ENST00000230538 / NM_001105206.3; = p.A774V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs863223685; called by muse, mutect2
- LAMTOR1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as COSV99194437; called by muse, mutect2, varscan2
- LCN1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs748720902, COSV99704508; called by muse, mutect2, varscan2
- LCT | c.4330G>A p.V1444M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs757039689, COSV99930157; called by muse, mutect2, varscan2
- LCT | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200115037, COSV99930159; called by muse, mutect2, varscan2
- LDHAL6B | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs776635266, COSV99896343; called by muse, mutect2, varscan2
- LENG9 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.503); catalogued as rs908914069; called by muse, mutect2
- LHFPL5 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as COSV100799003; called by muse, mutect2, varscan2
- LHFPL6 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV101095568; called by muse, mutect2
- LHX9 | c.1064C>A p.P355Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100436014; called by muse, varscan2
- LIFR | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs757644188, COSV99665063; called by muse, mutect2, varscan2
- LILRA6 | c.685A>T p.T229S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.098); catalogued as COSV99558224; called by muse, mutect2, varscan2
- LIMS2 | c.193G>A p.E65K (on ENST00000355119 / NM_001161403.3; = p.E89K on NM_017980.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs530155178, COSV99760714; called by muse, mutect2, varscan2
- LINGO4 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV100765021; called by muse, mutect2, varscan2
- LIPJ | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776965932, COSV100905925, COSV64245636; called by muse, mutect2, varscan2
- LIPK | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV101344995; called by muse, mutect2, varscan2
- LMO4 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100983999; called by muse, mutect2, varscan2
- LMTK2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV99807479; called by muse, mutect2, varscan2
- LMTK3 | c.2732G>A p.G911D | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs868535969, COSV99541018; called by muse, mutect2
- LRP4 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101066794; called by muse, mutect2, varscan2
- LRRC37B | c.2124-1G>T p.X708_splice | Splice Site (SNP) | VAF 98/192 reads (51%) | catalogued as COSV100496438; called by muse, mutect2, varscan2
- LRRC40 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100918832, COSV63943598; called by muse, mutect2, varscan2
- LRRC4B | c.1211T>C p.M404T | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100976003; called by muse, mutect2, varscan2
- LRRC7 | c.3872G>T p.R1291M (on ENST00000651989 / NM_001370785.2; = p.R1258M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV99228808; called by muse, mutect2
- LSM14B | c.663G>T p.R221S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.324); catalogued as COSV99444602; called by muse, mutect2, varscan2
- LTBP1 | c.2267T>C p.F756S (on ENST00000404816 / NM_206943.4; = p.F430S on NM_000627.4) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100617803; called by muse, mutect2, varscan2
- LTBP2 | c.5147C>T p.P1716L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100000797; called by muse, mutect2, varscan2
- LTBP2 | c.2806C>T p.Q936* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100000799; called by muse, mutect2, varscan2
- LURAP1 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV100915131; called by muse, mutect2, varscan2
- LYN | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV101319628; called by muse, mutect2, varscan2
- LYZ | c.299G>A p.S100N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99720188; called by muse, mutect2, varscan2
- MACF1 | c.6481C>T p.P2161S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV57108316; called by muse, mutect2, varscan2
- MAGEE1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100819482; called by muse, mutect2, varscan2
- MAMDC2 | c.1771G>A p.G591R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV101015706; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 27/52 reads (52%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP2K2 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs759998177, COSV99502601; called by muse, mutect2, varscan2
- MAPRE3 | c.353A>C p.N118T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99251960; called by muse, mutect2, varscan2
- MAT1A | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV64745378; called by muse, mutect2, varscan2
- MBLAC2 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as COSV100353210; called by muse, mutect2
- MCC | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as COSV100203077; called by muse, mutect2, varscan2
- MCF2L2 | c.1205G>A p.C402Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100193549; called by muse, mutect2, varscan2
- MCOLN2 | c.1493T>A p.I498N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99394131; called by muse, mutect2, varscan2
- MDC1 | c.4507G>C p.D1503H | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as COSV100903022, COSV64528060; called by muse, mutect2, varscan2
- MDN1 | c.8017C>A p.P2673T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV101021667; called by muse, mutect2, varscan2
- MDN1 | c.6614G>T p.S2205I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV101021456; called by muse, mutect2, varscan2
- MECP2 | c.672G>C p.M224I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100318389; called by muse, mutect2, varscan2
- MEF2C | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV100425954; called by muse, mutect2, varscan2
- MEGF11 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV99988781; called by muse, mutect2, varscan2
- MEP1A | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100042996; called by muse, mutect2, varscan2
- MFSD6L | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV61004435; called by muse, mutect2, varscan2
- MGA | c.4609G>A p.V1537M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV99581044; called by muse, mutect2, varscan2
- MGA | c.8569G>T p.G2857W (on ENST00000219905 / NM_001164273.1; = p.G2648W on NM_001080541.2) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99581048; called by muse, mutect2, varscan2
- MIA3 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1037527314, COSV100719517; called by muse, mutect2, varscan2
- MICAL2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99818079; called by muse, varscan2
- MICALL1 | c.2050A>G p.I684V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99317491; called by muse, mutect2, varscan2
- MID2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754364027, COSV99465355; called by muse, mutect2, varscan2
- MIER2 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53399329, COSV99316632; called by muse, mutect2, varscan2
- MIGA1 | c.1046G>A p.C349Y | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100889797; called by muse, mutect2, varscan2
- MIS18BP1 | c.983G>A p.G328E | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100173191, COSV60373729; called by muse, mutect2, varscan2
- MLXIP | c.2347C>A p.L783M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100039011; called by muse, mutect2, varscan2
- MOSPD2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.074); catalogued as COSV100996903; called by muse, mutect2, varscan2
- MOV10 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100659716; called by muse, mutect2, varscan2
- MPP7 | c.1551+1G>C p.X517_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100517729; called by muse, mutect2, varscan2
- MPRIP | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs776527696, COSV100506065; called by muse, mutect2, varscan2
- MR1 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as rs751056986, COSV51579872; called by muse, mutect2, varscan2
- MRGPRX2 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100316806; called by muse, mutect2, varscan2
- MROH6 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99435341; called by muse, mutect2, varscan2
- MRPL24 | c.182C>G p.T61R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs188054107, COSV100625869; called by muse, mutect2, varscan2
- MRPL44 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99285298; called by muse, mutect2, varscan2
- MRTO4 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV100367525; called by muse, mutect2, varscan2
- MST1 | c.609C>A p.A203= | Splice Region (SNP) | VAF 31/59 reads (53%) | catalogued as COSV99610989; called by muse, mutect2, varscan2
- MTA3 | c.697A>T p.T233S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV101290735; called by muse, mutect2, varscan2
- MTFR1 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 40/103 reads (39%) | catalogued as COSV100050335; called by muse, mutect2, varscan2
- MTNR1A | c.395G>C p.S132T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100208286; called by muse, mutect2, varscan2
- MTUS2 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.044); catalogued as COSV70917069; called by muse, mutect2
- MUC1 | c.3648C>A p.Y1216* (on ENST00000611571 / NM_001371720.1; = p.Y227* on NM_002456.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100104705, COSV58118887; called by muse, mutect2, varscan2
- MUC16 | c.26840G>A p.S8947N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.083); catalogued as COSV101200769; called by muse, mutect2, varscan2
- MUC16 | c.25817G>A p.R8606H | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs182118027, COSV67443664; called by muse, mutect2, varscan2
- MUC16 | c.25268G>A p.S8423N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.451); catalogued as COSV101200772; called by muse, mutect2
- MUC17 | c.6710C>T p.A2237V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs201523803; called by muse, mutect2, varscan2
- MUC5AC | c.14503C>A p.P4835T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.65); catalogued as COSV100611553; called by muse, mutect2, varscan2
- MUC5B | c.12613G>A p.E4205K | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV101500632; called by muse, mutect2, varscan2
- MUC6 | c.7142G>T p.S2381I | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100173224; called by muse, mutect2
- MXRA5 | c.3493C>T p.R1165W | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs759981443, COSV99478523; called by muse, mutect2, varscan2
- MYBBP1A | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as rs1263706146, COSV54602021; called by muse, mutect2, varscan2
- MYBPC3 | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99920822; called by muse, mutect2, varscan2
- MYH13 | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.262); catalogued as rs530640003, COSV99355014; called by muse, mutect2, varscan2
- MYLK2 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV101044901; called by muse, mutect2, varscan2
- MYO15A | c.8852C>A p.A2951D | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV52755733, COSV99233944; called by muse, mutect2, varscan2
- MYO1D | c.2914C>A p.L972M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.15); catalogued as COSV100532125; called by muse, mutect2, varscan2
- MYO7A | c.5267T>C p.L1756P | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101289232; called by mutect2, varscan2
- N4BP2 | c.4511A>G p.Q1504R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV54701374, COSV99789106; called by muse, mutect2, varscan2
- N4BP2L2 | c.1385-1G>C p.X462_splice | Splice Site (SNP) | VAF 17/37 reads (46%) | catalogued as rs373298163, COSV99912668; called by muse, mutect2, varscan2
- NALCN | c.5123A>G p.D1708G | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV99216917; called by muse, mutect2, varscan2
- NAV1 | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV99819419; called by muse, mutect2, varscan2
- NBEA | c.4066C>T p.H1356Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100082906; called by muse, varscan2
- NCOR1 | c.3691G>A p.G1231R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99251436; called by muse, mutect2, varscan2
- NCOR2 | c.3904del p.H1302Mfs*12 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as COSV100657106; called by mutect2, pindel, varscan2
- NDUFB2 | c.212G>A p.W71* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV99199987; called by muse, mutect2, varscan2
- NEU3 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99579663; called by muse, mutect2, varscan2
- NEURL3 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.184); catalogued as COSV100182475; called by muse, mutect2, varscan2
- NFE2L1 | c.1669C>A p.Q557K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV100671659; called by muse, mutect2, varscan2
- NGEF | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752947664, COSV99890339; called by muse, mutect2, varscan2
- NHLRC2 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as COSV63749780; called by muse, varscan2
- NID1 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs774575082, COSV99938037; called by muse, mutect2, varscan2
- NIM1K | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100390354; called by muse, mutect2, varscan2
- NIPAL1 | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99784516; called by muse, mutect2, varscan2
- NLE1 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99338959; called by muse, mutect2, varscan2
- NLE1 | c.963C>A p.S321= | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100681101; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRP1 | c.3223A>G p.T1075A | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV99335115; called by muse, mutect2, varscan2
- NLRP11 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs756743418, COSV100789791; called by muse, mutect2, varscan2
- NLRP2 | c.1532C>T p.T511I | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1464742024, COSV99672535; called by muse, mutect2, varscan2
- NLRP4 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100016106, COSV100016860; called by muse, mutect2, varscan2
- NOBOX | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99779608; called by muse, mutect2, varscan2
- NOC4L | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs764680094, COSV100223159; called by muse, mutect2, varscan2
- NOVA1 | c.992C>G p.T331S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99948388; called by muse, mutect2, varscan2
- NPHS1 | c.2557G>A p.G853R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100800165; called by muse, mutect2, varscan2
- NPM2 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV99235794; called by muse, mutect2, varscan2
- NPRL3 | c.1538T>C p.F513S (on ENST00000611875 / NM_001077350.3; = p.F488S on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV99550036; called by muse, mutect2, varscan2
- NRCAM | c.2777T>G p.L926R (on ENST00000379028 / NM_001371124.1; = p.L910R on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100695223; called by muse, mutect2, varscan2
- NRK | c.2504C>T p.A835V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99688790; called by muse, mutect2
- NTNG1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs750959424, COSV99635274; called by muse, mutect2, varscan2
- NTNG1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as rs1272290487, COSV53990273; called by muse, mutect2, varscan2
- NUDT17 | c.440G>T p.S147I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100493036; called by muse, mutect2, varscan2
- NUMA1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100706476; called by muse, mutect2, varscan2
- NUP205 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1377436466, COSV99607396; called by mutect2, varscan2
- NUP62 | c.314C>G p.T105S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100352262; called by muse, mutect2, varscan2
- NUP93 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs764196494, COSV100360410; called by muse, varscan2
- OAZ2 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs940432539, COSV100386458; called by muse, mutect2, varscan2
- OBSCN | c.3526G>A p.V1176M | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1213588048, COSV99482570; called by muse, mutect2, varscan2
- OBSCN | c.11383C>T p.L3795F | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52807906, COSV99482571; called by muse, mutect2, varscan2
- OCA2 | c.2079+1G>A p.X693_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as CS161213, COSV100668404; called by muse, mutect2
- ONECUT2 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs773105719, COSV101525740; called by muse, mutect2, varscan2
- OPHN1 | c.632A>G p.N211S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV100830686, COSV62779989; called by muse, mutect2, varscan2
- OR11L1 | c.523A>G p.N175D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.4); catalogued as COSV100869467; called by muse, mutect2
- OR1A1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs779762532, COSV100410806; called by muse, mutect2, varscan2
- OR1J4 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.378); catalogued as rs200712755; called by muse, mutect2, varscan2
- OR2AT4 | c.598del p.Q200Rfs*37 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs999134663; called by pindel, varscan2
- OR4X2 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56582840; called by muse, mutect2, varscan2
- OR51Q1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV100333043; called by muse, mutect2, varscan2
- OR52E4 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.158); catalogued as rs151237451, COSV57626044; called by muse, mutect2, varscan2
- OR5AN1 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100004316; called by muse, mutect2, varscan2
- OR5K1 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 22/166 reads (13%) | catalogued as COSV60304774; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs746200712; called by mutect2, varscan2
- OR7C1 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99934806; called by muse, mutect2, varscan2
- OR9K2 | c.978del p.K326Nfs*3 (on ENST00000305377; = p.K304Nfs*3 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | catalogued as rs1249976011; called by mutect2, pindel, varscan2
- OSGEPL1 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99918478; called by muse, mutect2, varscan2
- OTX1 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56996452; called by muse, mutect2, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- OXNAD1 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99551362; called by muse, mutect2, varscan2
- PABPC3 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs537580022, COSV99879811; called by muse, mutect2, varscan2
- PABPC4 | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100790910; called by muse, mutect2
- PADI4 | c.1631G>A p.R544K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64924762; called by muse, mutect2
- PAGE1 | c.218G>C p.C73S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV101093994; called by muse, mutect2, varscan2
- PAICS | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | PolyPhen benign (0.216); catalogued as COSV99947859; called by muse, mutect2, varscan2
- PALM | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV52767309, COSV99214662; called by muse, mutect2, varscan2
- PARP3 | c.1538G>T p.S513I | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101290672; called by muse, mutect2, varscan2
- PARVG | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV63561844; called by muse, mutect2, varscan2
- PAX2 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV100695335; called by muse, mutect2
- PAX2 | c.1144G>T p.E382* (on ENST00000428433 / NM_003987.5; = p.E359* on NM_000278.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | catalogued as COSV100695337; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PC | c.1562G>A p.S521N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100540868; called by muse, mutect2, varscan2
- PCDH19 | c.2467C>A p.L823M (on ENST00000373034 / NM_001184880.2; = p.L776M on NM_020766.3) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV55268163; called by muse, mutect2, varscan2
- PCDHB13 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as rs782784632, COSV99507623; called by muse, mutect2, varscan2
- PCDHB6 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV50739561; called by muse, varscan2
- PCDHGA1 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV65296709; called by muse, mutect2, varscan2
- PCDHGA3 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.08); catalogued as rs762455729, COSV53980221, COSV54036945; called by muse, mutect2, varscan2
- PCDHGA6 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as rs781113576, COSV99539028; called by muse, mutect2, varscan2
- PCDHGB6 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV99543918; called by muse, mutect2, varscan2
- PCLO | c.2479G>C p.D827H | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV100435826, COSV100436042; called by muse, mutect2
- PCNX2 | c.2713T>C p.Y905H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99268952; called by muse, mutect2, varscan2
- PDE12 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489366621, COSV60818340; called by muse, mutect2, varscan2
- PDGFRB | c.1968T>A p.S656R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99940880; called by muse, mutect2, varscan2
- PEX16 | c.360-1G>T p.X120_splice | Splice Site (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99572330; called by muse, mutect2, varscan2
- PFAS | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as COSV100119079; called by muse, mutect2, varscan2
- PGAM5 | c.192G>A p.R64= | Splice Region (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100453080; called by muse, mutect2, varscan2
- PGAP3 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV100328660; called by muse, mutect2, varscan2
- PGBD2 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs139567720; called by muse, varscan2
- PGLYRP2 | c.8A>G p.Q3R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV99484224; called by muse, mutect2, varscan2
- PGLYRP3 | c.1008G>A p.W336* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as COSV99319870; called by muse, mutect2, varscan2
- PGR | c.2029C>A p.P677T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV99678887; called by muse, mutect2, varscan2
- PHACTR4 | c.1541G>A p.S514N (on ENST00000373839 / NM_001350159.2; = p.S524N on NM_023923.4) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100868486; called by muse, mutect2
- PHF14 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV101301840; called by muse, mutect2, varscan2
- PHF2 | c.2147C>T p.T716M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.813); catalogued as rs368672670; called by muse, varscan2
- PHGDH | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101025193; called by muse, mutect2, varscan2
- PHKA2 | c.3377C>A p.S1126* | Nonsense Mutation (SNP) | VAF 16/31 reads (52%) | catalogued as CM1414388, COSV101177010, COSV101177328; called by muse, mutect2, varscan2
- PHKA2 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV101177329, COSV66053795; called by muse, mutect2, varscan2
- PHLDB3 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99415897; called by muse, mutect2, varscan2
- PI4KA | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as rs1330537695, COSV99747937; called by muse, mutect2, varscan2
- PIAS4 | c.714G>C p.R238S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99519005; called by muse, mutect2, varscan2
- PID1 | c.287T>C p.L96P (on ENST00000354069 / NM_001330156.1; = p.L94P on NM_017933.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100819771; called by muse, mutect2, varscan2
- PIK3C2B | c.4333C>T p.R1445W | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs779951277, COSV100916198; called by muse, mutect2, varscan2
- PIK3C2B | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100915074; called by muse, mutect2, varscan2
- PITRM1 | c.3068C>A p.P1023H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99829434; called by muse, mutect2, varscan2
- PKD1L2 | c.2171T>C p.L724S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV100216888; called by muse, mutect2
- PKHD1 | c.5017G>A p.A1673T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100584129, COSV61891915; called by muse, mutect2, varscan2
- PKLR | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as COSV100712980; called by muse, mutect2, varscan2
- PKN3 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99403865; called by muse, mutect2
- PLAC8 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100274559; called by muse, mutect2, varscan2
- PLEKHA6 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs142044407; called by muse, varscan2
- PLEKHM2 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV101009186; called by muse, mutect2, varscan2
- PLOD3 | c.1961T>C p.V654A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99778193; called by muse, mutect2, varscan2
- PLVAP | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV99391789; called by muse, mutect2, varscan2
- PLXNA2 | c.1559G>A p.C520Y | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100885698; called by muse, mutect2, varscan2
- PLXNA3 | c.3532G>A p.D1178N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100860172; called by muse, mutect2
- PLXNA4 | c.3255C>A p.I1085= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100326214; called by muse, mutect2
- PLXND1 | c.3440C>T p.A1147V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100140241; called by muse, mutect2, varscan2
- PM20D1 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100900230, COSV65649700; called by muse, mutect2, varscan2
- PNMA3 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as COSV100937652; called by muse, mutect2, varscan2
- POLA1 | c.2744T>A p.I915N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100985714; called by muse, mutect2, varscan2
- POM121C | c.3406G>A p.G1136S (on ENST00000607367; = p.G894S on NM_001099415.3) | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs369689784; called by muse, mutect2, varscan2
- POP1 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs989634283, COSV62892879; called by muse, mutect2, varscan2
- PPP1R13L | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100714853; called by muse, mutect2
- PPP1R3F | c.1060+2T>C p.X354_splice | Splice Site (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99278947; called by muse, mutect2, varscan2
- PPP1R9A | c.2684G>T p.R895L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs139020369, COSV99196818; called by muse, mutect2, varscan2
- PPP2R5E | c.925T>A p.F309I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100518758; called by muse, mutect2, varscan2
- PPP6R3 | c.2300C>T p.A767V (on ENST00000393800 / NM_001352375.2; = p.A687V on NM_018312.5) | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs763455439, COSV99677171; called by muse, mutect2, varscan2
- PRAMEF18 | c.113del p.P38Hfs*15 | Frame Shift Del (DEL) | VAF 56/324 reads (17%) | catalogued as rs1340144927; called by mutect2, varscan2
- PRDM15 | c.2260T>C p.Y754H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99520712; called by muse, varscan2
- PRDX5 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV99134802; called by muse, mutect2, varscan2
- PRKAR1B | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100816799; called by muse, mutect2
- PRKAR2B | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV99708527; called by muse, mutect2, varscan2
- PRKDC | c.4058C>T p.P1353L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as rs767489623, COSV100042163; called by muse, mutect2, varscan2
- PRKG2 | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100020332; called by muse, mutect2, varscan2
- PRORP | c.257del p.L86* | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs760446387; called by mutect2, varscan2
- PROSER3 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99994665; called by muse, mutect2, varscan2
- PRPF18 | c.953T>C p.L318S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV101058848; called by muse, mutect2, varscan2
- PRPF40A | c.2713A>G p.K905E | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV101344218; called by muse, mutect2, varscan2
- PRR11 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.087); catalogued as COSV51878368, COSV99231735; called by muse, mutect2, varscan2
- PRSS8 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99571721; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSD4 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99831360; called by muse, mutect2, varscan2
- PSG6 | c.985+1G>A p.X329_splice | Splice Site (SNP) | VAF 12/256 reads (5%) | catalogued as COSV99414402; called by muse, mutect2
- PSMA7 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100065222; called by muse, mutect2, varscan2
- PSMC2 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV53007043; called by muse, mutect2, varscan2
- PSMD2 | c.2600C>T p.T867M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100031946; called by muse, mutect2, varscan2
- PSMF1 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99850696; called by muse, mutect2, varscan2
- PSTK | c.524G>A p.C175Y | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100924789; called by muse, mutect2, varscan2
- PTPN13 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs948576214, COSV100365237; called by muse, mutect2, varscan2
- PTPRF | c.4097C>T p.T1366M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751913526, COSV100741109; called by muse, mutect2, varscan2
- PTPRN | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99833772; called by muse, mutect2, varscan2
- PTPRN2 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.187); catalogued as rs993906186, COSV67020352; called by muse, mutect2, varscan2
- PXDNL | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.454); catalogued as rs377224751; called by muse, varscan2
- RAI1 | c.2765G>T p.G922V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99884737; called by muse, mutect2, varscan2
- RANBP2 | c.4079G>C p.S1360T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV51705448, COSV99312899; called by muse, mutect2, varscan2
- RANBP2 | c.5545G>C p.A1849P | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.091); catalogued as COSV51709727, COSV99312900; called by muse, mutect2, varscan2
- RAP1GAP | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99265667; called by muse, mutect2
- RAP1GDS1 | c.448G>A p.A150T (on ENST00000408927 / NM_001100427.2; = p.A151T on NM_021159.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs368890275; called by muse, mutect2, varscan2
- RAPGEF4 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.335); catalogued as COSV99911298; called by muse, mutect2, varscan2
- RAPSN | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV100100347; called by muse, mutect2, varscan2
- RASD2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.381); catalogued as rs755742181, COSV99332874; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBFOX1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.776); catalogued as rs748167936, COSV60965473; called by muse, mutect2, varscan2
- RBM12 | c.2767G>T p.G923C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100467913; called by muse, mutect2, varscan2
- RBM39 | c.95G>C p.S32T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as COSV99488806; called by muse, mutect2, varscan2
- RBMS2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as COSV100008625; called by muse, mutect2, varscan2
- RBMX2 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100564832; called by muse, mutect2, varscan2
- RECQL4 | c.3121G>T p.G1041W | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100020772; called by muse, mutect2, varscan2
- REG1A | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.458); catalogued as rs1301727307, COSV99286881, COSV99286939; called by muse, mutect2
- RELCH | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99902602; called by muse, mutect2, varscan2
- REV1 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV51485386, COSV99301298; called by muse, mutect2, varscan2
- RFPL1 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.842); catalogued as COSV100585866; called by muse, mutect2, varscan2
- RFTN1 | c.1518G>T p.E506D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.366); catalogued as COSV61918892; called by muse, mutect2, varscan2
- RGS12 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100376127; called by muse, mutect2, varscan2
- RGS14 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV101281740; called by muse, mutect2, varscan2
- RIOK2 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs771275716, COSV99300156; called by muse, mutect2, varscan2
- RIPPLY3 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100289404; called by muse, mutect2, varscan2
- RLF | c.3545C>T p.T1182I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV101035616; called by muse, mutect2
- RNF113A | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV101007092; called by muse, mutect2, varscan2
- ROBO3 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101185145; called by muse, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
735 further variants in this file (337 protein-altering or splice-affecting, 363 silent, 35 other) are not listed here.
